CCDI case PBCPKE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Other and unspecified female genital organs.
https://portal.gdc.cancer.gov/cases/7b20d746-105a-4239-a5b2-19625e7062ca

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Labium majus; Age at diagnosis: 1.5 years (556 days).

Biospecimens (3 samples)
- Sample 0DWTAC: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWTBM: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWTC1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
